Gene-level copy-number profile of tumor specimen CUPP-B38Q-TTM1-A from CCG case CUPP-B38Q, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 78.7 years (28,740 days).
Specimen CUPP-B38Q-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae27f25d-12e6-4f9c-9f92-74491944e334.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,365 have no estimate.
https://portal.gdc.cancer.gov/files/596aa322-6004-465e-ada6-cc0372916cb7

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 41; copy number 2: 776; copy number 3: 7,125; copy number 4: 5,108; copy number 5: 40,063; copy number 6: 1,863; copy number 7: 2,160; copy number 8: 866; copy number 9: 141; copy number 10: 29; copy number 11: 23; copy number 12: 5; copy number 13: 9; copy number 14: 6; copy number 15: 4; copy number 16: 2; copy number 17: 6; copy number 18: 1; copy number 19: 1; copy number 21: 4; copy number 23: 17; copy number 24: 3; copy number 40: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,226,523–30,226,615, 1 gene: AL021921.1.
- chr4:9,567,474–9,691,786, 1 gene (within-gene range 0–3): AC105916.1.
- chr4:9,677,308–9,677,934, 1 gene: ENPP7P11.
- chr15:28,679,405–28,682,252, 1 gene (within-gene range 0–5): AC055876.2.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 82 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 17 (within-gene range 3–17): PRAMEF6, PRAMEF28P.
- chr1:62,189,131–62,189,953, 1 gene, copy number 24: PIGPP2.
- chr1:172,370,189–172,613,534, 4 genes, copy number 11–12 (within-gene range 8–12): PIGC, C1orf105, SUCO, RNU6-693P.
- chr1:178,006,136–178,037,950, 2 genes, copy number 11 (within-gene range 5–11): CRYZL2P, AL359075.1.
- chr1:185,518,651–185,657,168, 5 genes, copy number 11: AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1.
- chr1:234,837,976–234,838,069, 1 gene, copy number 11: RNY4P16.
- chr2:130,073,535–130,129,222, 2 genes, copy number 14 (within-gene range 4–14): POTEF, AC018865.1.
- chr3:126,672,106–126,673,223, 1 gene, copy number 12: AC078867.1.
- chr3:129,163,606–129,183,922, 2 genes, copy number 11: AC108673.3, CNBP.
- chr3:129,314,771–129,316,286, 1 gene, copy number 17 (within-gene range 5–17): H1-10.
- chr4:9,034,519–9,381,269, 1 gene, copy number 23 (within-gene range 2–23): AC108519.1.
- chr4:9,234,385–9,236,046, 1 gene, copy number 23: USP17L15.
- chr4:9,243,879–9,369,070, 17 genes, copy number 13–23: USP17L17, USP17L18, USP17L19, USP17L20, USP17L21, USP17L22, USP17L23, USP17L24, USP17L25, USP17L26, USP17L5, USP17L27, USP17L28, USP17L29, USP17L9P, USP17L30, USP17L6P.
- chr7:63,931,141–63,931,968, 1 gene, copy number 13: SLC25A1P3.
- chr8:143,833,270–143,840,973, 4 genes, copy number 21: AC234917.1, NRBP2, MIR6845, AC234917.2.
- chr10:44,712–46,884, 1 gene, copy number 40: AL713922.1.
- chr10:31,756,042–31,756,136, 1 gene, copy number 11: Y_RNA.
- chr10:133,430,394–133,431,318, 1 gene, copy number 14: OR6L2P.
- chr11:823,634–832,883, 2 genes, copy number 11 (within-gene range 5–11): AP006621.1, CRACR2B.
- chr11:2,129,112–2,141,238, 1 gene, copy number 14 (within-gene range 5–14): IGF2.
- chr11:2,129,121–2,129,964, 1 gene, copy number 14: AC132217.1.
- chr11:2,134,134–2,134,209, 1 gene, copy number 14 (within-gene range 5–14): MIR483.
- chr11:111,908,564–111,926,871, 4 genes, copy number 13: CRYAB, HSPB2, HSPB2-C11orf52, C11orf52.
- chr15:20,940,380–21,058,440, 3 genes, copy number 17 (within-gene range 4–17): LINC01193, OR11J2P, OR11J5P.
- chr15:21,990,074–22,095,857, 5 genes, copy number 11 (within-gene range 10–14): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,095,472, 2 genes, copy number 11: OR4M2, OR4N4.
- chr15:60,347,134–60,402,883, 2 genes, copy number 13: ANXA2, AC087385.1.
- chr15:63,597,353–63,602,428, 1 gene, copy number 11 (within-gene range 9–11): FBXL22.
- chr16:629,239–636,366, 2 genes, copy number 24 (within-gene range 6–24): WFIKKN1, METTL26.
- chr16:678,504–679,777, 2 genes, copy number 16 (within-gene range 8–16): LINC02867, Z92544.2.
- chr16:720,581–726,954, 2 genes, copy number 12 (within-gene range 7–12): ANTKMT, CCDC78.
- chr16:1,305,547–1,309,413, 1 gene, copy number 19 (within-gene range 6–19): AC120498.9.
- chr19:797,075–821,955, 4 genes, copy number 15: PTBP1, MIR4745, PLPPR3, MIR3187.
- chr21:13,654,073–13,654,356, 1 gene, copy number 18: AL050303.2.

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
